Somatic mutation profile of tumor specimen TCGA-A3-3308-01A (aliquot TCGA-A3-3308-01A-01D-0966-08) from TCGA case TCGA-A3-3308, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 77.4 years (28,287 days).
Specimen TCGA-A3-3308-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40d853da-f98d-4018-b5a3-ce207f41c6d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3308-11A (Solid Tissue Normal), aliquot TCGA-A3-3308-11A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0afb118d-f380-4b82-a2bc-2ac218a178a9

The open-access MAF lists 86 somatic variants for this specimen: 66 protein-altering or splice-affecting, 20 silent.
By variant classification: Missense Mutation 48, Silent 20, Frame Shift Del 10, In Frame Del 2, Nonsense Mutation 2, Splice Site 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.437del p.L146* | Frame Shift Del (DEL) | VAF 43/215 reads (20%) | hotspot (GDC flag); catalogued as rs1114167627, COSV64292458; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.634+1G>A p.X212_splice | Splice Site (SNP) | VAF 78/381 reads (20%) | hotspot (GDC flag); catalogued as CS110219, CS1314438, COSV64295775, COSV64297457, COSV64302278; called by muse, mutect2, varscan2
- ASB10 | c.1366C>T p.R456C (on ENST00000420175 / NM_001142459.2; = p.R441C on NM_080871.4) | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs776358265, COSV99318067; called by muse, mutect2, varscan2
- BRCA2 | c.8399C>G p.P2800R | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80359087; ClinVar: uncertain significance; called by muse, mutect2
- CDCP2 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779292002; called by muse, mutect2, varscan2
- CSMD3 | c.10740T>G p.F3580L (on ENST00000297405 / NM_001363185.1; = p.F3411L on NM_052900.3) | Missense Mutation (SNP) | VAF 212/420 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.772); catalogued as rs1484852694; called by muse, mutect2, varscan2
- FN1 | c.331A>C p.T111P | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100118561; called by muse, mutect2, varscan2
- GRIK1 | c.1421G>A p.R474K | Missense Mutation (SNP) | VAF 58/287 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.579); catalogued as rs963257580; called by muse, mutect2, varscan2
- HTR1A | c.259G>C p.V87L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.24); catalogued as rs201675006; called by mutect2, varscan2
- MAP3K19 | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 71/278 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); catalogued as rs373802326; called by muse, mutect2, varscan2
- MFAP5 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs865910671; called by muse, mutect2, varscan2
- MSR1 | c.1319C>A p.S440* | Nonsense Mutation (SNP) | VAF 38/244 reads (16%) | catalogued as COSV50512301; called by muse, mutect2, varscan2
- NYNRIN | c.1537G>A p.A513T | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs748667976, COSV101230554; called by muse, mutect2, varscan2
- ORC1 | c.1936C>T p.R646W | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs537583215, COSV65365412; called by muse, mutect2
- PTPRZ1 | c.4991A>T p.K1664I | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV101099398; called by mutect2, varscan2
- RSPH10B | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs374498782; called by muse, mutect2, varscan2
- SPRY4 | c.73C>T p.R25W (on ENST00000434127 / NM_001127496.3; = p.R48W on NM_030964.4) | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs753427357, COSV59986357; called by muse, mutect2, varscan2
- TDRD10 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 107/440 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs768196430, COSV100872929; called by muse, mutect2, varscan2
- TRAM1L1 | c.1045G>A p.G349R | Missense Mutation (SNP) | VAF 122/530 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV60291867; called by muse, mutect2, varscan2
- ADAMTSL5 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.033); called by muse, mutect2
- ASPM | c.3354T>A p.D1118E | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- ATP1A4 | c.1952C>G p.A651G | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2
- ATP5MD | c.131del p.Y44Ffs*4 | Frame Shift Del (DEL) | VAF 19/150 reads (13%) | called by mutect2, pindel, varscan2
- BAP1 | c.1975_1977del p.K659del | In Frame Del (DEL) | VAF 39/171 reads (23%) | called by pindel, varscan2
- CCDC163 | c.296C>G p.A99G | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- CCDC57 | c.416A>G p.N139S | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- CDH6 | c.1021_1024del p.K341Cfs*36 | Frame Shift Del (DEL) | VAF 30/150 reads (20%) | called by mutect2, pindel, varscan2
- DCAF13 | c.61T>G p.L21V | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DERL3 | c.526A>G p.I176V | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- EPS8 | c.215C>T p.T72I | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, varscan2
- ERO1A | c.1124A>C p.K375T | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EXOSC10 | c.285del p.S95Rfs*9 | Frame Shift Del (DEL) | VAF 85/460 reads (18%) | called by mutect2, pindel, varscan2
- HMCN1 | c.16672A>G p.T5558A | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IL17RB | c.1004T>A p.L335H | Missense Mutation (SNP) | VAF 75/371 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- INAVA | c.1282_1285del p.H428Tfs*3 | Frame Shift Del (DEL) | VAF 83/389 reads (21%) | called by pindel, varscan2
- INTS1 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KMT2D | c.3957T>A p.H1319Q | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- LGSN | c.744T>G p.Y248* | Nonsense Mutation (SNP) | VAF 13/97 reads (13%) | called by muse, mutect2, varscan2
- LRRN3 | c.1750A>G p.N584D | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- MANEAL | c.408G>T p.K136N | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.108); called by mutect2, varscan2
- OR2L2 | c.418T>C p.C140R | Missense Mutation (SNP) | VAF 72/407 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- PATJ | c.1694T>C p.I565T | Missense Mutation (SNP) | VAF 80/355 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPIL4 | c.1059T>G p.D353E | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP1R7 | c.647G>C p.G216A | Missense Mutation (SNP) | VAF 51/490 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTK2B | c.2188C>T p.L730F | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RCC1 | c.119T>A p.L40Q | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- RIF1 | c.6628A>C p.I2210L | Missense Mutation (SNP) | VAF 43/203 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- RPE65 | c.640G>T p.A214S | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SETD2 | c.5465del p.P1822Qfs*16 | Frame Shift Del (DEL) | VAF 27/115 reads (23%) | called by mutect2, pindel, varscan2
- SHMT2 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- SULT2A1 | c.398dup p.W134Lfs*8 | Frame Shift Ins (INS) | VAF 48/236 reads (20%) | called by mutect2, pindel, varscan2
- SWT1 | c.1585_1587del p.E529del | In Frame Del (DEL) | VAF 27/143 reads (19%) | called by pindel, varscan2
- SYCP2L | c.2055del p.E686Kfs*8 | Frame Shift Del (DEL) | VAF 29/170 reads (17%) | called by mutect2, pindel, varscan2
- TAF1 | c.4438G>T p.D1480Y (on ENST00000373790 / NM_138923.4; = p.D1501Y on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/215 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TFB1M | c.48del p.T17Rfs*9 | Frame Shift Del (DEL) | VAF 23/106 reads (22%) | called by mutect2, pindel, varscan2
- TMPRSS3 | c.573-8_573-1del p.X191_splice | Splice Site (DEL) | VAF 22/72 reads (31%) | called by mutect2, pindel, varscan2
- TTN | c.29632G>C p.A9878P (on ENST00000591111; = p.A8951P on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/127 reads (24%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TTN | c.22852C>T p.H7618Y (on ENST00000591111; = p.H6691Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/332 reads (10%) | PolyPhen benign (0.003); called by muse, mutect2
- TXNDC11 | c.2729C>A p.A910D (on ENST00000356957 / NM_001303447.2; = p.A883D on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- USH2A | c.10720G>C p.G3574R | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- VDAC3 | c.613T>C p.S205P | Missense Mutation (SNP) | VAF 18/396 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); called by muse, mutect2
- VHL | c.515_518del p.P172Rfs*29 | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | called by mutect2, pindel, varscan2
- WASL | c.1076C>A p.P359Q | Missense Mutation (SNP) | VAF 76/268 reads (28%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- WDHD1 | c.1947G>C p.M649I | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF347 | c.410del p.N137Ifs*21 | Frame Shift Del (DEL) | VAF 84/382 reads (22%) | called by mutect2, pindel, varscan2
- ZSCAN2 | c.1095dup p.E366Rfs*7 | Frame Shift Ins (INS) | VAF 58/295 reads (20%) | called by mutect2, pindel, varscan2
- ANKRD55 | c.1158T>C p.D386= | Silent (SNP) | VAF 180/678 reads (27%) | called by muse, mutect2, varscan2
- EFCC1 | c.1633C>T p.L545= | Silent (SNP) | VAF 41/208 reads (20%) | catalogued as COSV101459994; called by muse, mutect2, varscan2
- FAM47B | c.1140C>T p.Y380= | Silent (SNP) | VAF 38/111 reads (34%) | called by muse, mutect2, varscan2
- IMPG2 | c.3276T>C p.C1092= | Silent (SNP) | VAF 46/316 reads (15%) | called by muse, mutect2, varscan2
- INPP5F | c.3207T>A p.S1069= | Silent (SNP) | VAF 56/258 reads (22%) | called by muse, mutect2, varscan2
- IQGAP1 | c.3486C>T p.F1162= | Silent (SNP) | VAF 33/174 reads (19%) | catalogued as COSV99185475; called by muse, mutect2, varscan2
- KIF25 | c.609G>A p.T203= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as rs147571413; called by muse, mutect2, varscan2
- LMO7 | c.453G>A p.V151= (on ENST00000357063; = p.V166= on NM_005358.5) | Silent (SNP) | VAF 63/234 reads (27%) | catalogued as COSV58531561; called by muse, mutect2, varscan2
- LRIT1 | c.1782G>A p.E594= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV64512860; called by muse, mutect2, varscan2
- MED6 | c.18C>T p.I6= | Silent (SNP) | VAF 14/59 reads (24%) | called by muse, mutect2, varscan2
- MYO1D | c.2334G>A p.T778= | Silent (SNP) | VAF 24/104 reads (23%) | catalogued as rs969564116; called by muse, mutect2, varscan2
- NCAPG2 | c.2712A>G p.Q904= | Silent (SNP) | VAF 79/403 reads (20%) | catalogued as rs752571821; called by muse, mutect2, varscan2
- NLRP7 | c.444C>T p.D148= | Silent (SNP) | VAF 148/685 reads (22%) | catalogued as rs781097722, COSV60171380; called by muse, mutect2, varscan2
- NOS1 | c.3231T>A p.A1077= | Silent (SNP) | VAF 11/82 reads (13%) | called by muse, mutect2, varscan2
- OR5H2 | c.6G>A p.S2= | Silent (SNP) | VAF 77/333 reads (23%) | catalogued as rs756216447, COSV62351076; called by muse, mutect2, varscan2
- PHF2 | c.780C>T p.H260= | Silent (SNP) | VAF 27/157 reads (17%) | catalogued as rs539206245, COSV100823244; called by muse, mutect2, varscan2
- PRG3 | c.282G>A p.R94= | Silent (SNP) | VAF 45/222 reads (20%) | called by muse, mutect2, varscan2
- RNF17 | c.493T>C p.L165= | Silent (SNP) | VAF 35/142 reads (25%) | catalogued as rs1397730095; called by muse, mutect2, varscan2
- TPT1 | c.153T>C p.N51= | Silent (SNP) | VAF 43/162 reads (27%) | called by muse, mutect2, varscan2
- ZBTB10 | c.939T>C p.S313= | Silent (SNP) | VAF 29/176 reads (16%) | called by muse, mutect2, varscan2
